Somatic mutation profile of tumor specimen TCGA-B8-A54I-01A (aliquot TCGA-B8-A54I-01A-21D-A33K-10) from TCGA case TCGA-B8-A54I, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 48.5 years (17,722 days).
Specimen TCGA-B8-A54I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb8102ca-688d-47c6-a52c-95fe44a78af5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54I-10A (Blood Derived Normal), aliquot TCGA-B8-A54I-10A-01D-A33K-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cef153a-7f45-43f8-b039-ce83e5ab5e59

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 42, Silent 13, Frame Shift Del 6, Nonsense Mutation 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA3 | c.3548G>T p.R1183L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV99293873; called by muse, mutect2, varscan2
- ADGRG4 | c.8885C>T p.P2962L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99797345; called by muse, mutect2, varscan2
- ANO5 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs1393118989, COSV100202343; called by muse, mutect2, varscan2
- APOL6 | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.359); catalogued as rs374537194; called by muse, mutect2, varscan2
- ATG5 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100576705; called by muse, mutect2
- ATG5 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100576640, COSV100576707; called by muse, mutect2
- C19orf44 | c.580A>T p.R194W | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV99685531; called by muse, mutect2, varscan2
- CASR | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs201520875, COSV56141570; called by muse, mutect2, varscan2
- CHI3L2 | c.72A>T p.G24= | Splice Region (SNP) | VAF 8/80 reads (10%) | catalogued as rs1208354152, COSV100869337; called by muse, mutect2, varscan2
- CHMP5 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99794706; called by muse, mutect2, varscan2
- CHRNA4 | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100937504; called by muse, mutect2, varscan2
- CPA2 | c.484A>C p.K162Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs780109016, COSV99744351; called by muse, mutect2, varscan2
- DDX24 | c.635T>A p.F212Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100428170; called by muse, mutect2, varscan2
- EXT1 | c.1873A>G p.I625V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs773393953, COSV65486819; called by muse, mutect2
- FAAP100 | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | catalogued as COSV100585637; called by muse, mutect2, varscan2
- FLNC | c.6023A>G p.K2008R | Missense Mutation (SNP) | VAF 47/230 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100368956; called by muse, mutect2, varscan2
- GPD2 | c.2019G>T p.L673F | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV100133751; called by muse, mutect2, varscan2
- HEATR5B | c.5864G>A p.G1955E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs761893882, COSV99250404; called by muse, mutect2, varscan2
- IGSF22 | c.1037T>A p.V346E | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100080606; called by muse, mutect2, varscan2
- IKBKB | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs1064795873, COSV100645808, COSV60598802, COSV60598896; ClinVar: uncertain significance; called by muse, mutect2
- KANK2 | c.2180G>A p.R727Q (on ENST00000586659 / NM_001379562.1; = p.R735Q on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as rs138941748; called by muse, mutect2, varscan2
- KIF5C | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.384); catalogued as COSV101276228; called by muse, mutect2, varscan2
- LAMTOR1 | c.377T>C p.F126S | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99194469; called by muse, mutect2
- LARS2 | c.220A>T p.I74F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV99648406; called by muse, mutect2, varscan2
- LBR | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV99687800; called by muse, mutect2, varscan2
- LILRA4 | c.1420C>G p.P474A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.056); catalogued as COSV52492367, COSV99393460; called by muse, mutect2, varscan2
- LRP2 | c.1016A>T p.N339I | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99790678; called by muse, mutect2, varscan2
- MEGF10 | c.2184T>A p.D728E | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99175859; called by muse, varscan2
- MPHOSPH9 | c.476G>C p.S159T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100187368; called by muse, mutect2, varscan2
- MRTFA | c.3013C>T p.L1005F | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1467163061, COSV99960746; called by muse, mutect2
- PCDHGB3 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99549008; called by muse, mutect2, varscan2
- PLXNA1 | c.1048A>T p.K350* | Nonsense Mutation (SNP) | VAF 44/148 reads (30%) | catalogued as COSV99304329; called by muse, mutect2, varscan2
- PTRH2 | c.43del p.S15Vfs*53 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV52244421; called by mutect2, pindel
- RBM33 | c.630A>T p.E210D | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs374113890; called by muse, mutect2, varscan2
- RRBP1 | c.2888T>A p.L963Q (on ENST00000377813 / NM_001365613.2; = p.L530Q on NM_004587.3) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99854814; called by muse, mutect2, varscan2
- RTTN | c.6123G>C p.L2041F | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99734079; called by muse, mutect2, varscan2
- SLC8B1 | c.847A>G p.N283D | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1425275780, COSV99176854; called by muse, mutect2, varscan2
- SUGP1 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55923029, COSV99895392; called by muse, mutect2, varscan2
- TIMM17A | c.117T>G p.N39K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100939037; called by muse, mutect2, varscan2
- USP8 | c.2431C>A p.Q811K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100209405; called by muse, varscan2
- VWF | c.7397C>G p.A2466G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV54636123, COSV99780533; called by muse, mutect2, varscan2
- ZNF18 | c.205T>G p.W69G | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503204; called by muse, mutect2, varscan2
- ZNF343 | c.945C>G p.H315Q | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99601721; called by muse, mutect2, varscan2
- ZNF440 | c.76A>G p.R26G | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV100407785; called by muse, mutect2
- C1QB | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CD200R1 | c.726del p.K242Nfs*14 (on ENST00000471858 / NM_170780.3; = p.K265Nfs*14 on NM_138806.4) | Frame Shift Del (DEL) | VAF 75/587 reads (13%) | called by mutect2, pindel, varscan2
- FAM13B | c.1653-7_1653-2del p.X551_splice | Splice Site (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- NEDD8 | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- POLDIP2 | c.397_400del p.Y133Ifs*4 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- RFC5 | c.602del p.G201Efs*2 | Frame Shift Del (DEL) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- SEPTIN5 | c.227dup p.S77Qfs*3 | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- TOM1 | c.299del p.V100Gfs*35 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- TOM1L2 | c.418del p.I140Yfs*5 (on ENST00000379504 / NM_001350333.2; = p.I90Yfs*5 on NM_001033551.3) | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- FAAP100 | c.1902G>A p.E634= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1194521112, COSV100585638; called by muse, mutect2, varscan2
- LRRIQ4 | c.109T>C p.L37= | Silent (SNP) | VAF 10/266 reads (4%) | catalogued as COSV100540434; called by muse, mutect2
- NADK2 | c.924C>T p.L308= (on ENST00000381937 / NM_001085411.3; = p.L145= on NM_153013.4) | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV99237993; called by muse, mutect2, varscan2
- OLFML2A | c.1614C>T p.D538= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1448450449, COSV56582046; called by muse, mutect2, varscan2
- OR10G4 | c.660C>A p.I220= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV100305045, COSV57977173; called by muse, mutect2
- PHYH | c.630A>G p.P210= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV99538416; called by muse, mutect2, varscan2
- PTH2R | c.126G>A p.L42= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV99783012; called by muse, mutect2
- RASAL3 | c.594C>T p.V198= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs750861558, COSV59141750; called by muse, mutect2, varscan2
- RRBP1 | c.2889G>T p.L963= (on ENST00000377813 / NM_001365613.2; = p.L530= on NM_004587.3) | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV99854812; called by muse, mutect2, varscan2
- SLCO5A1 | c.189T>C p.C63= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99481299; called by muse, mutect2, varscan2
- SPTBN2 | c.5613T>A p.A1871= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV100020710; called by muse, mutect2, varscan2
- VWCE | c.1035G>A p.V345= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100076261; called by muse, mutect2, varscan2
- YY1AP1 | c.319C>T p.L107= (on ENST00000295566 / NM_139118.2; = p.L30= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV99804850; called by muse, mutect2
